Gene-level copy-number profile of specimen HCM-CSHL-0837-D01-85P from HCMI case HCM-CSHL-0837-D01, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Intraductal papillary-mucinous carcinoma, non-invasive; Tissue or organ of origin: Pancreas, NOS; Tumor grade: GX; Age at diagnosis: 67.7 years (24,735 days).
Specimen HCM-CSHL-0837-D01-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1f619aa-6a55-4842-9cb7-3cd267528d81.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0837-D01-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/6643fff8-d883-489f-872d-9cf37d86c9a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,669; copy number 2: 55,125; copy number 3: 121.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
